Gene-level copy-number profile of tumor specimen AP-HKYN-9M from APOLLO case AP-HKYN, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3.
Specimen AP-HKYN-9M: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1efc9713-595b-4b10-bb4b-4162cd414e4f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-HKYN-C5 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/73d05bab-cecc-4aa0-8a60-66f895a54e31

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 561; copy number 1: 4,171; copy number 2: 26,152; copy number 3: 22,483; copy number 4: 5,493; copy number 5: 35; copy number 6: 6.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:85,731,371–85,998,263, 7 genes: AL355615.1, SMIM11P1, RNU4-72P, Y_RNA, AL450338.1, AL450338.2, RNU4-12P.
- chr9:14,921,337–14,922,334, 1 gene: LDHAP4.
- chr9:21,231,266–22,455,740, 40 genes: IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr21:10,649,400–10,649,835, 1 gene: IGHV1OR21-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 41 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:51,383,448–51,665,048, 5 genes, copy number 6: ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2.
- chr5:68,215,756–68,301,821, 1 gene, copy number 6: PIK3R1.
- chr5:69,492,292–71,259,238, 35 genes, copy number 5 (within-gene range 4–5): OCLN, RNU6-724P, GTF2H2C, NAIPP3, AC139495.2, GUSBP3, AC139495.1, GUSBP13, AC131392.1, CDH12P2, SERF1B, SMN2, AC140134.1, NAIPP2, CDH12P3, AC138866.1, GUSBP14, GTF2H2B, AC146944.2, NAIPP1, AC146944.1, GUSBP15, GUSBP16, AC139272.1, CDH12P1, SERF1A, SMN1, AC139834.1, NAIP, GTF2H2, OCLNP1, NAIPP4, CDH12P4, GUSBP9, GUSBP17.

Autosomal genes at a single copy (total copy number 1): 4,171. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
